Somatic mutation profile of tumor specimen HCM-BROD-0047-C71-02A (aliquot HCM-BROD-0047-C71-02A-01D-A77E-36) from HCMI case HCM-BROD-0047-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.3 years (22,404 days).
Specimen HCM-BROD-0047-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fa26b36-8a79-47bb-9253-f138ef0c14ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0047-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0047-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23039391-ae6f-4361-855f-c09a10818113

The open-access MAF lists 146 somatic variants for this specimen: 95 protein-altering or splice-affecting, 33 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 33, 3'UTR 7, Frame Shift Del 6, Nonsense Mutation 5, RNA 5, Intron 5, In Frame Del 3, Frame Shift Ins 2, Splice Site 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 74/111 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 228/305 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ASB15 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 27/164 reads (16%) | catalogued as COSV99306913; called by muse, mutect2, varscan2
- ATAD2 | c.825T>A p.D275E | Missense Mutation (SNP) | VAF 116/162 reads (72%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149531312; called by muse, mutect2, varscan2
- C3orf56 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371883407; called by muse, mutect2, varscan2
- CERKL | c.1393C>T p.R465W (on ENST00000339098 / NM_001030311.2; = p.R439W on NM_201548.5) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139300604, COSV100184198, COSV59204341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLEC4A | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | catalogued as rs201965264; called by muse, mutect2
- DNAH3 | c.9871C>T p.R3291W | Missense Mutation (SNP) | VAF 136/303 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772203216, COSV54535961; called by muse, mutect2, varscan2
- ITGA4 | c.2669G>A p.C890Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67897802; called by muse, mutect2
- KEL | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 253/954 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147851584, CM165859, COSV62335323; called by muse, mutect2, varscan2
- KIR2DL4 | c.981+1G>T p.X327_splice (on ENST00000396284; = p.X253_splice on NM_001080770.2) | Splice Site (SNP) | VAF 35/331 reads (11%) | catalogued as COSV58488408; called by muse, mutect2, varscan2
- LIPC | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 187/468 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.438); catalogued as rs756311428; called by muse, mutect2, varscan2
- LRRC4B | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65350301; called by muse, mutect2
- LTBP1 | c.3169G>T p.E1057* (on ENST00000404816 / NM_206943.4; = p.E731* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 96/270 reads (36%) | catalogued as COSV55383251; called by muse, mutect2, varscan2
- MRGPRX4 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1444628507, COSV58589735; called by muse, mutect2, varscan2
- MUC16 | c.24178G>A p.D8060N | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.125); catalogued as rs541350099, COSV101198208; called by muse, mutect2, varscan2
- OR2T4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 163/381 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs141022739; called by muse, mutect2, varscan2
- OR2T6 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs182818153, COSV63215979; called by muse, mutect2
- PEX6 | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 159/396 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs575358435; called by muse, mutect2, varscan2
- PLCB2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs938166611; called by muse, mutect2, varscan2
- PPP1R16B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs376987738; called by muse, mutect2, varscan2
- PRSS23 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 8/231 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432789007; called by muse, mutect2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 78/132 reads (59%) | catalogued as rs146650273; called by pindel, varscan2
- RNF17 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 71/111 reads (64%) | catalogued as COSV55046264; called by muse, mutect2, varscan2
- SEC31B | c.3087G>T p.E1029D | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs756259622; called by muse, mutect2
- SHANK1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53253397, COSV53258492; called by muse, mutect2, varscan2
- SLC26A1 | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs565674546; called by muse, mutect2, varscan2
- TAS1R3 | c.2030G>C p.R677P | Missense Mutation (SNP) | VAF 139/351 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV59562358; called by muse, mutect2, varscan2
- TNFSF9 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 148/340 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs753168707; called by muse, varscan2
- TRAV21 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs762806352; called by muse, mutect2, varscan2
- TRPM5 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 146/331 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs376847854; called by muse, mutect2, varscan2
- TTC34 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 78/115 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs769408367; called by muse, mutect2, varscan2
- XRN1 | c.1346+5G>A | Splice Region (SNP) | VAF 42/112 reads (38%) | catalogued as rs749503524; called by muse, mutect2, varscan2
- ZSCAN5C | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 119/363 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.428); catalogued as rs762862197; called by muse, mutect2, varscan2
- AUTS2 | c.1223G>T p.R408I | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BORCS5 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- C12orf50 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEL | c.1433_1435del p.P478del (on ENST00000673714; = p.P475del on NM_001807.6) | In Frame Del (DEL) | VAF 78/323 reads (24%) | called by pindel, varscan2
- CHST2 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- CIT | c.3526G>A p.G1176R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 225/271 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH3 | c.11274_11288del p.E3758_Y3763delinsD | In Frame Del (DEL) | VAF 66/261 reads (25%) | called by mutect2, pindel, varscan2
- DNAH8 | c.10162T>C p.C3388R | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- DOCK9 | c.723_725del p.N241del (on ENST00000376460 / NM_001366676.2; = p.N242del on NM_015296.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 37/73 reads (51%) | called by pindel, varscan2
- ENPP4 | c.9A>T p.L3F | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.7407T>A p.F2469L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- FST | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA2 | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- GOLGA8J | c.72del p.N24Kfs*49 | Frame Shift Del (DEL) | VAF 67/287 reads (23%) | called by mutect2, pindel, varscan2
- HIF3A | c.682C>G p.H228D (on ENST00000377670 / NM_152795.4; = p.H159D on NM_022462.4) | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HOXA3 | c.762_771del p.M255Hfs*20 | Frame Shift Del (DEL) | VAF 64/315 reads (20%) | called by mutect2, pindel, varscan2
- HOXD11 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFI6 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2
- ITGA6 | c.593A>T p.K198I | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- KCNG3 | c.1068C>A p.D356E | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.63); called by muse, mutect2
- KCNMA1 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- KLK2 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- LY6G6F-LY6G6D | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPKAPK5 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MSH5 | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- MUC16 | c.18163A>G p.T6055A | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MUC16 | c.6512C>A p.T2171K | Missense Mutation (SNP) | VAF 110/343 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1B | c.1673A>T p.N558I | Missense Mutation (SNP) | VAF 151/436 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- NCKAP5L | c.1170_1171insTG p.P391Cfs*41 | Frame Shift Ins (INS) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- NFASC | c.3039A>G p.I1013M | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2
- NNT | c.3241_3243delinsTT p.R1081Lfs*9 | Frame Shift Del (DEL) | VAF 55/245 reads (22%) | called by pindel, varscan2*
- NOX3 | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- NUP210 | c.2944T>C p.Y982H | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- OR2A2 | c.594A>G p.I198M | Missense Mutation (SNP) | VAF 167/533 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- OR2L3 | c.645T>A p.C215* | Nonsense Mutation (SNP) | VAF 112/310 reads (36%) | called by muse, varscan2
- OR4K5 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- OS9 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCDHA2 | c.1618G>C p.A540P | Missense Mutation (SNP) | VAF 480/642 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PCMT1 | c.805G>C p.V269L | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFKL | c.865T>A p.F289I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PKHD1 | c.11335C>A p.P3779T | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHA7 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POM121 | c.2367del p.F790Sfs*51 (on ENST00000434423; = p.F525Sfs*51 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 87/819 reads (11%) | called by mutect2, pindel, varscan2
- PRKY | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 91/128 reads (71%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- PRLHR | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PSPC1 | c.260dup p.N88Kfs*44 | Frame Shift Ins (INS) | VAF 65/148 reads (44%) | called by mutect2, pindel, varscan2
- RFNG | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS10 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC25A51 | c.432G>C p.L144F | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC4A2 | c.3608T>C p.V1203A | Missense Mutation (SNP) | VAF 87/354 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC7A14 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 38/582 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLU7 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SUZ12 | c.2042T>C p.L681P | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM131L | c.2898G>T p.R966S | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TRRAP | c.11378T>C p.L3793P (on ENST00000359863 / NM_001244580.1; = p.L3764P on NM_003496.3) | Missense Mutation (SNP) | VAF 170/824 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTPAL | c.445+1G>A p.X149_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | called by muse, varscan2
- ZFYVE1 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ZGRF1 | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ZNF708 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF721 | c.2604_2605del p.Y869Cfs*3 (on ENST00000338977; = p.Y881Cfs*3 on NM_133474.4) | Frame Shift Del (DEL) | VAF 88/285 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.90C>G p.R30= | Silent (SNP) | VAF 82/241 reads (34%) | called by muse, mutect2, varscan2
- APOBR | c.2205G>A p.A735= (on ENST00000431282; = p.A744= on NM_018690.4) | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs369577053; called by muse, mutect2, varscan2
- ARSF | c.990T>C p.D330= | Silent (SNP) | VAF 58/84 reads (69%) | called by muse, mutect2, varscan2
- BEGAIN | c.1431C>T p.S477= | Silent (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1860C>T p.D620= | Silent (SNP) | VAF 109/138 reads (79%) | catalogued as rs569086347, COSV57895134; called by muse, mutect2, varscan2
- CATSPERG | c.2271C>T p.R757= | Silent (SNP) | VAF 229/604 reads (38%) | called by muse, mutect2, varscan2
- CPA1 | c.858C>A p.V286= | Silent (SNP) | VAF 116/603 reads (19%) | called by muse, mutect2, varscan2
- DIDO1 | c.4143C>T p.D1381= | Silent (SNP) | VAF 168/403 reads (42%) | called by muse, mutect2, varscan2
- DUSP26 | c.528G>T p.V176= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as COSV56361050; called by muse, mutect2, varscan2
- DYSF | c.2718C>T p.D906= | Silent (SNP) | VAF 120/329 reads (36%) | catalogued as rs772806555, COSV50266247; called by muse, mutect2, varscan2
- FLG | c.1563G>T p.G521= | Silent (SNP) | VAF 230/642 reads (36%) | catalogued as rs763639841; called by muse, mutect2, varscan2
- FOXD2 | c.1014G>C p.A338= | Silent (SNP) | VAF 17/236 reads (7%) | called by muse, mutect2
- FZD10 | c.1422C>T p.I474= | Silent (SNP) | VAF 115/301 reads (38%) | catalogued as COSV99969621; called by muse, mutect2, varscan2
- GIMAP8 | c.1638G>A p.A546= | Silent (SNP) | VAF 57/216 reads (26%) | catalogued as rs897850406, COSV56231089; called by muse, mutect2, varscan2
- GUCY2D | c.1311G>A p.P437= | Silent (SNP) | VAF 161/208 reads (77%) | catalogued as rs775635196, COSV54696534; called by muse, mutect2, varscan2
- HAS1 | c.219C>T p.F73= | Silent (SNP) | VAF 157/249 reads (63%) | called by muse, mutect2, varscan2
- HMCN2 | c.12579G>A p.A4193= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs942933262, COSV52983544; called by muse, mutect2, varscan2
- KIFC2 | c.1227T>C p.N409= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as rs777245430; called by muse, mutect2
- NLRP2 | c.1764C>T p.C588= | Silent (SNP) | VAF 287/448 reads (64%) | catalogued as rs781443340, COSV54759813; called by muse, mutect2, varscan2
- OCLN | c.198G>T p.R66= | Silent (SNP) | VAF 17/464 reads (4%) | called by muse, mutect2
- PPL | c.1194G>A p.P398= | Silent (SNP) | VAF 71/181 reads (39%) | catalogued as rs752842442, COSV100630759; called by muse, mutect2, varscan2
- PRC1 | c.525C>T p.V175= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- RPS3A | c.210T>C p.S70= | Silent (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- SCN5A | c.873C>T p.N291= | Silent (SNP) | VAF 86/186 reads (46%) | catalogued as rs376515775; ClinVar: likely benign; called by muse, mutect2, varscan2
- SELE | c.315G>A p.R105= | Silent (SNP) | VAF 88/237 reads (37%) | catalogued as rs759912786, COSV60974350; called by muse, mutect2, varscan2
- SORBS1 | c.3750G>A p.L1250= (on ENST00000361941 / NM_001034954.2; = p.L642= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- TMEM132D | c.42G>A p.S14= | Silent (SNP) | VAF 26/456 reads (6%) | catalogued as rs1464488554, COSV70613792; called by muse, mutect2
- TRRAP | c.11379C>T p.L3793= (on ENST00000359863 / NM_001244580.1; = p.L3764= on NM_003496.3) | Silent (SNP) | VAF 172/838 reads (21%) | called by muse, mutect2, varscan2
- TTBK1 | c.1977A>C p.P659= | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- TTN | c.48555T>A p.G16185= (on ENST00000591111; = p.G8761= on NM_003319.4) | Silent (SNP) | VAF 18/310 reads (6%) | called by muse, mutect2
- VAX2 | c.606G>A p.A202= | Silent (SNP) | VAF 88/212 reads (42%) | catalogued as rs782471705, COSV52265915; called by muse, mutect2, varscan2
- WWC1 | c.1467C>T p.A489= | Silent (SNP) | VAF 212/239 reads (89%) | called by muse, mutect2, varscan2
- ZNF18 | c.303G>A p.V101= | Silent (SNP) | VAF 147/199 reads (74%) | catalogued as rs1217188275, COSV59550512; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 12/120 reads (10%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- C5orf60 | n.1675C>A | RNA (SNP) | VAF 36/568 reads (6%) | called by muse, mutect2
- EAF2 | c.*22A>G | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- EEF2 | c.613-150_613-149del | Intron (DEL) | VAF 20/127 reads (16%) | called by mutect2, pindel
- FAM172BP | n.237A>G | RNA (SNP) | VAF 16/181 reads (9%) | called by muse, mutect2
- GIT2 | c.1393-1363C>G | Intron (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- GUCY2EP | n.1194G>A | RNA (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2
- HCN1 | c.*4C>T | 3'UTR (SNP) | VAF 143/369 reads (39%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1114G>T | RNA (SNP) | VAF 84/160 reads (53%) | called by muse, mutect2, varscan2
- KCNQ1 | c.386+16152G>A | Intron (SNP) | VAF 122/339 reads (36%) | catalogued as rs768249738; called by muse, mutect2, varscan2
- KRIT1 | c.*46G>C | 3'UTR (SNP) | VAF 69/278 reads (25%) | called by muse, mutect2, varscan2
- NDUFS3 | c.231+62G>C | Intron (SNP) | VAF 179/496 reads (36%) | called by muse, mutect2, varscan2
- QRICH2 | c.*45C>T | 3'UTR (SNP) | VAF 106/143 reads (74%) | catalogued as rs770433642, COSV53156824; called by muse, mutect2, varscan2
- RPL31 | c.*2C>A | 3'UTR (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- SCN4B | c.*2757G>A | 3'UTR (SNP) | VAF 146/343 reads (43%) | catalogued as rs1232026663; called by muse, mutect2, varscan2
- SLC11A2 | c.*2235T>A | 3'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- SNORD114-14 | chr14:100969830 A>G | 5'Flank (SNP) | VAF 18/36 reads (50%) | called by muse, varscan2
- TCP10L3 | n.2602A>T | RNA (SNP) | VAF 76/213 reads (36%) | called by muse, mutect2, varscan2
